Gene-level copy-number profile of tumor specimen BLGSP-71-23-00401-01A from CGCI case BLGSP-71-23-00401, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 5.7 years (2,093 days).
Specimen BLGSP-71-23-00401-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7a556ea4-fb26-44c8-a08c-8687de05de44.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-23-00401-11B (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,772 have no estimate.
https://portal.gdc.cancer.gov/files/294a0a05-a151-494a-8573-5295b2f3725e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 4,668; copy number 2: 46,602; copy number 3: 6,326; copy number 4: 1,013; copy number 5: 195; copy number 6: 37; copy number 7: 8.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:112,967–126,123, 2 genes: AC069287.1, CICP23.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 240 genes in 57 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:92,969,604–93,010,351, 3 genes, copy number 5: RNU6-970P, RN7SL692P, RNU6-210P.
- chr1:120,432,204–120,434,052, 1 gene, copy number 5: PFN1P2.
- chr1:120,849,674–120,914,238, 4 genes, copy number 6 (within-gene range 2–6): AC253572.1, RNVU1-19, PPIAL4A, AC241377.3.
- chr1:147,019,656–147,124,285, 6 genes, copy number 6: AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P.
- chr1:160,670,148–160,780,140, 6 genes, copy number 5–7: SETP9, AL121985.1, CD48, SLAMF7, AL121985.3, AL121985.2.
- chr1:167,591,392–167,630,674, 2 genes, copy number 5 (within-gene range 3–5): AL031733.1, AL031733.2.
- chr1:171,090,901–171,227,788, 6 genes, copy number 5: FMO3, MIR1295A, MIR1295B, FMO6P, FMO2, AL021026.1.
- chr1:174,996,524–175,012,027, 3 genes, copy number 6: RNU6-307P, Z99127.3, CACYBP.
- chr1:175,156,986–175,192,999, 1 gene, copy number 6: KIAA0040.
- chr1:182,573,634–182,684,576, 5 genes, copy number 5–6: RNASEL, Metazoa_SRP, RGS16, LINC01686, RGS8.
- chr1:192,517,190–192,660,311, 3 genes, copy number 5: AL136987.1, RGS1, RGS13.
- chr1:198,597,724–198,757,476, 4 genes, copy number 6–7: AL157402.1, PTPRC, AL157402.2, PEBP1P3.
- chr1:226,631,690–226,739,323, 3 genes, copy number 6: ITPKB, ITPKB-IT1, ITPKB-AS1.
- chr2:45,169,616–45,211,673, 2 genes, copy number 5: AC009236.2, AC009236.1.
- chr2:88,691,673–88,806,612, 2 genes, copy number 5: RPIA, ANKRD36BP2.
- chr2:90,114,838–90,235,370, 9 genes, copy number 5 (within-gene range 5–6): IGKV3D-15, IGKV2D-14, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7.
- chr2:144,517,978–144,521,477, 4 genes, copy number 5 (within-gene range 4–5): ZEB2-AS1, AC009951.2, AC009951.1, AC009951.3.
- chr3:30,606,601–30,699,576, 3 genes, copy number 6: TGFBR2, AC096921.1, AC096921.2.
- chr3:169,902,980–169,998,373, 7 genes, copy number 5: KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1.
- chr3:183,487,551–183,555,706, 2 genes, copy number 5: KLHL6, KLHL6-AS1.
- chr3:187,958,775–188,003,990, 3 genes, copy number 5: LINC01991, AC092941.1, AC092941.2.
- chr4:83,233,512–83,284,914, 4 genes, copy number 5: AC114781.2, AC114781.3, AC114781.1, COQ2.
- chr4:143,351,515–143,426,013, 2 genes, copy number 6: AC097658.3, RPSAP36.
- chr6:18,363,417–18,368,644, 2 genes, copy number 5: DDX18P3, IMPDH1P9.
- chr6:26,501,221–26,546,933, 4 genes, copy number 5: BTN1A1, RNU6-502P, HCG11, HMGN4.
- chr7:50,274,790–50,405,101, 3 genes, copy number 5: AC020743.3, IKZF1, AC124014.1.
- chr8:11,368,402–11,564,694, 6 genes, copy number 5 (within-gene range 3–5): FAM167A-AS1, RN7SL293P, RNU6-1084P, FAM167A, BLK, AC022239.1.
- chr9:37,046,835–37,358,149, 10 genes, copy number 5 (within-gene range 5–6): AL161781.1, LINC01400, AL512604.3, EBLN3P, AL512604.2, ZCCHC7, Y_RNA, AL512604.1, Y_RNA, RNU6-677P.
- chr10:96,292,685–96,338,564, 2 genes, copy number 6: AL136181.1, DNTT.
- chr13:30,419,519–30,429,758, 2 genes, copy number 5: LINC01058, UBE2L5.
- chr13:40,407,122–40,611,127, 2 genes, copy number 5 (within-gene range 4–5): RN7SKP2, AL133318.1.
- chr13:41,431,248–41,470,871, 4 genes, copy number 5: OR7E36P, OR7E155P, OR7E37P, RGCC.
- chr13:50,812,988–51,024,120, 3 genes, copy number 5 (within-gene range 2–5): RNA5SP28, RNASEH2B-AS1, RNASEH2B.
- chr14:22,314,490–22,613,215, 80 genes, copy number 5 (broad region; genes not listed).
- chr16:21,834,569–21,919,156, 2 genes, copy number 6: NPIPB4, SMG1P4.
- chr19:28,316,705–28,429,490, 3 genes, copy number 5: AC005580.1, AC093074.1, AC005307.1.
- chr21:43,140,523–43,162,277, 2 genes, copy number 5–7: FRGCA, AP001631.1.
- chr21:44,107,373–44,210,114, 5 genes, copy number 6 (within-gene range 3–6): PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1.
- chr22:21,991,099–22,043,934, 6 genes, copy number 5: PRAMENP, IGLVI-70, IGLV4-69, IGLVI-68, AC245452.4, AC245452.3.
- chr22:22,043,618–22,046,591, 2 genes, copy number 5: IGLV10-67, AC245452.2.

Autosomal genes at a single copy (total copy number 1): 1,825. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
